Somatic mutation profile of cancer-model specimen HCM-BROD-0226-C43-85M (Adherent Cell Line, passage 10; aliquot HCM-BROD-0226-C43-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0226-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 31.1 years (11,364 days).
Specimen HCM-BROD-0226-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 10.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b10765ce-f7b1-42ba-bdf5-cef0163017b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0226-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0226-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29b0ca0f-9da1-4f56-8e57-ebdf4a33f0b4

The open-access MAF lists 322 somatic variants for this specimen: 195 protein-altering or splice-affecting, 80 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 80, Intron 27, Nonsense Mutation 12, 3'UTR 7, RNA 6, Frame Shift Del 5, 5'UTR 4, Splice Region 4, Splice Site 4, 5'Flank 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- USH2A | c.11507C>T p.P3836L | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1553257685; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.5509G>A p.V1837I | Missense Mutation (SNP) | VAF 424/856 reads (50%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.931); catalogued as rs1311657115; called by muse, mutect2, varscan2
- ADAMTS19 | c.3248G>T p.R1083M | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs778211763; called by muse, mutect2, varscan2
- AGBL2 | c.1631+1G>C p.X544_splice | Splice Site (SNP) | VAF 32/32 reads (100%) | catalogued as rs781494422; called by muse, mutect2
- AKR1C2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 121/136 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV66334675; called by muse, mutect2, varscan2
- AZU1 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.06); catalogued as rs563340651, COSV52140138, COSV99297438; called by muse, mutect2, varscan2
- BARX1 | c.610G>A p.G204S | Missense Mutation (SNP) | VAF 98/104 reads (94%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as COSV54159447; called by muse, mutect2, varscan2
- BNC1 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 125/254 reads (49%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.84); catalogued as COSV61756405; called by muse, mutect2, varscan2
- CASR | c.2530G>A p.E844K (on ENST00000490131; = p.E921K on NM_000388.4) | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs755629322, COSV56136433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELSR2 | c.6641C>T p.P2214L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs762738190; called by muse, mutect2, varscan2
- CFAP57 | c.2843G>A p.R948K | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV65264448; called by muse, varscan2
- CFAP74 | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.074); catalogued as rs1480671943; called by muse, mutect2, varscan2
- CHFR | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 264/439 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs746187833; called by muse, mutect2, varscan2
- CMYA5 | c.10735G>A p.E3579K | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1327396628; called by muse, mutect2, varscan2
- COL1A1 | c.3560G>C p.G1187A | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.878); catalogued as CD042192, CM900072; called by muse, mutect2, varscan2
- CRTC3 | c.515G>A p.S172N | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.262); catalogued as rs1168065091; called by muse, mutect2, varscan2
- CSMD1 | c.3212C>T p.S1071F (on ENST00000520002; = p.S1070F on NM_033225.6) | Missense Mutation (SNP) | VAF 101/120 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs368592556, COSV59302376; called by muse, mutect2, varscan2
- DCAF8L1 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 33/34 reads (97%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV101491474; called by muse, mutect2, varscan2
- DUS2 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1291390109; called by muse, mutect2
- EP400 | c.6169G>A p.E2057K | Missense Mutation (SNP) | VAF 108/187 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as COSV57788000; called by muse, mutect2, varscan2
- GDF2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 115/123 reads (93%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs782015913; called by muse, varscan2
- GLI3 | c.2701G>T p.D901Y | Missense Mutation (SNP) | VAF 329/707 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101230067; called by muse, mutect2, varscan2
- GPRC6A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369734914, COSV59953059; called by muse, mutect2
- GRM3 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.478); catalogued as rs1006712026, COSV64476081, COSV64480377; called by muse, varscan2
- HK3 | c.2659G>T p.E887* | Nonsense Mutation (SNP) | VAF 16/374 reads (4%) | catalogued as rs945052976; called by muse, mutect2
- HRH4 | c.599G>A p.S200N | Missense Mutation (SNP) | VAF 132/149 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs1257526905; called by muse, mutect2, varscan2
- IPCEF1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 59/72 reads (82%) | SIFT tolerated (0.14); PolyPhen benign (0.15); catalogued as rs777433578; called by muse, mutect2, varscan2
- ITIH5 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 127/137 reads (93%) | SIFT tolerated (0.39); PolyPhen benign (0.013); catalogued as rs747038918, COSV53670364; called by muse, mutect2, varscan2
- KLC4 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769752349; called by muse, mutect2, varscan2
- KRBA1 | c.2884C>T p.P962S | Missense Mutation (SNP) | VAF 127/243 reads (52%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.999); catalogued as rs1457120871; called by muse, mutect2, varscan2
- LAIR1 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 202/343 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104398424; called by muse, mutect2, varscan2
- LAMA5 | c.1141C>T p.Q381* | Nonsense Mutation (SNP) | VAF 366/634 reads (58%) | catalogued as COSV53353414; called by muse, mutect2, varscan2
- LCE2C | c.109C>G p.P37A | Missense Mutation (SNP) | VAF 84/385 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.115); catalogued as rs940170503; called by muse, mutect2, varscan2
- LCE5A | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 220/416 reads (53%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.485); catalogued as rs1423735491, COSV57500082; called by muse, mutect2, varscan2
- LCT | c.3784G>A p.E1262K | Missense Mutation (SNP) | VAF 66/214 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV51547403; called by muse, mutect2, varscan2
- LGSN | c.171G>A p.M57I | Missense Mutation (SNP) | VAF 66/70 reads (94%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs777977947; called by muse, mutect2, varscan2
- LILRA2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 171/348 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV52192017; called by muse, mutect2, varscan2
- LNX1 | c.745G>A p.E249K (on ENST00000263925 / NM_001126328.3; = p.E153K on NM_032622.2) | Missense Mutation (SNP) | VAF 93/98 reads (95%) | SIFT tolerated (0.45); PolyPhen benign (0.075); catalogued as COSV55783809; called by muse, mutect2, varscan2
- MAP3K10 | c.1901C>T p.S634F | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV53420614; called by muse, mutect2, varscan2
- MMP16 | c.1073T>C p.F358S | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54159894; called by muse, mutect2, varscan2
- MMP28 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.145); catalogued as rs1555606553; called by muse, mutect2, varscan2
- MORC1 | c.1624C>T p.P542S | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.065); catalogued as COSV51721062; called by muse, mutect2, varscan2
- MSGN1 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 108/242 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.039); catalogued as rs753107164, COSV99808762; called by muse, mutect2, varscan2
- MUC16 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 91/161 reads (57%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.197); catalogued as rs769571404, COSV67446414; called by muse, mutect2, varscan2
- NGF | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 58/99 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1384874552, COSV65687959; called by muse, mutect2, varscan2
- NUDC | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 59/466 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as rs1184679216; called by muse, mutect2, varscan2
- OGDHL | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs771174825, COSV65102591; called by muse, mutect2, varscan2
- OR2M3 | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as rs540802469; called by mutect2, varscan2
- OR2T10 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 161/377 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV57896851; called by muse, mutect2, varscan2
- OR4A16 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 101/117 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100125205; called by muse, mutect2, varscan2
- OTOGL | c.6148C>T p.P2050S (on ENST00000547103; = p.P2041S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV54019653, COSV99037891; called by muse, mutect2, varscan2
- OTULIN | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV99419977; called by muse, mutect2, varscan2
- PBRM1 | c.714+1G>A p.X238_splice | Splice Site (SNP) | VAF 19/22 reads (86%) | catalogued as COSV56312611; called by muse, mutect2, varscan2
- PCLO | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 106/221 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs1438564754, COSV100432059, COSV100432821; called by muse, mutect2, varscan2
- PGM1 | c.1277C>G p.T426S | Missense Mutation (SNP) | VAF 133/401 reads (33%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.537); catalogued as rs1400763909; called by muse, mutect2, varscan2
- PIGR | c.2012G>A p.R671Q | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs755581398; called by muse, mutect2, varscan2
- PLPP4 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 81/90 reads (90%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV68040652; called by muse, mutect2, varscan2
- PLXNB2 | c.2903C>G p.S968C | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV63779968, COSV63784167; called by muse, mutect2, varscan2
- PTPRT | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 428/735 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs868376470, COSV61962472; called by muse, mutect2, varscan2
- QSOX1 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 75/134 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as COSV100852834; called by muse, mutect2, varscan2
- RASAL2 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772116589, COSV62713663; called by muse, mutect2, varscan2
- RGPD3 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1256649916; called by muse, mutect2, varscan2
- RUFY3 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 40/44 reads (91%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1560511264, COSV56914898; called by muse, mutect2, varscan2
- SLC38A4 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56965130; called by muse, mutect2, varscan2
- SLC46A3 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as rs780949242, COSV57180391; called by muse, mutect2, varscan2
- SLCO4C1 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 99/176 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60519705; called by muse, mutect2, varscan2
- ST14 | c.2218C>T p.P740S | Missense Mutation (SNP) | VAF 130/141 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754225370; called by muse, mutect2, varscan2
- SYCP2L | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 31/64 reads (48%) | catalogued as rs773905945, COSV51657690; called by muse, mutect2
- TJP3 | c.2596C>T p.H866Y | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53662182; called by muse, mutect2
- TMPRSS15 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53039559; called by muse, mutect2, varscan2
- TNFRSF4 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 144/235 reads (61%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.757); catalogued as rs780860323, COSV99767298; called by muse, mutect2, varscan2
- TNXB | c.11476G>A p.A3826T (on ENST00000647633; = p.A3579T on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 168/576 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs745472837; called by muse, mutect2, varscan2
- TRPV6 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 180/400 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs772265505, COSV63891048; called by muse, mutect2, varscan2
- TTN | c.73168G>A p.E24390K (on ENST00000591111; = p.E16966K on NM_003319.4) | Missense Mutation (SNP) | VAF 63/118 reads (53%) | PolyPhen benign (0.062); catalogued as COSV59967335, COSV60029937; called by muse, mutect2, varscan2
- UBD | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100589565; called by muse, mutect2
- UNC5CL | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 131/279 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs753447230; called by muse, mutect2
- USHBP1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV99394477; called by muse, mutect2, varscan2
- WDR87 | c.4337G>A p.G1446E | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs957749656, COSV58192883; called by muse, mutect2, varscan2
- WDR92 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.152); catalogued as rs1409525550; called by muse, mutect2, varscan2
- XDH | c.3847C>T p.R1283* | Nonsense Mutation (SNP) | VAF 108/267 reads (40%) | catalogued as rs751921838, CM159356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF10 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV99940093; called by muse, mutect2, varscan2
- ZNF181 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs764799472; called by muse, mutect2, varscan2
- ABCB1 | c.2108T>C p.L703P | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ABCF1 | c.2506G>T p.G836C (on ENST00000326195 / NM_001025091.2; = p.G798C on NM_001090.3) | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADGRE5 | c.1714G>C p.V572L (on ENST00000242786 / NM_078481.4; = p.V479L on NM_001784.5) | Missense Mutation (SNP) | VAF 148/247 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- AHNAK2 | c.11792T>C p.L3931P | Missense Mutation (SNP) | VAF 187/402 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ALDH3A2 | c.648_658delinsA p.D217Vfs*10 | Frame Shift Del (DEL) | VAF 63/276 reads (23%) | called by pindel, varscan2*
- ALOXE3 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 150/501 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.056); called by mutect2, varscan2
- ANGPTL1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ANKFY1 | c.1295C>T p.T432I | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- APAF1 | c.3329A>T p.K1110M (on ENST00000551964 / NM_181861.2; = p.K1056M on NM_001160.3) | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- APOH | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARAP3 | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 186/325 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ARHGAP30 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 155/290 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG16L1 | c.795-5T>A | Splice Region (SNP) | VAF 36/116 reads (31%) | called by muse, mutect2, varscan2
- C1orf127 | c.1024G>A p.V342I | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C6orf15 | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CARM1 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 103/150 reads (69%) | called by muse, mutect2, varscan2
- CD163 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 96/166 reads (58%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDC42BPB | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 75/206 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CDX4 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- CHGB | c.1331G>C p.G444A | Missense Mutation (SNP) | VAF 166/510 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CLIP1 | c.1021T>C p.S341P | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- COMMD1 | c.352G>C p.G118R | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- CR1 | c.5728A>G p.S1910G | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CRACDL | c.1114G>T p.D372Y | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DDX46 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 54/98 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DNAH3 | c.4207G>A p.V1403M | Missense Mutation (SNP) | VAF 132/268 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DOCK9 | c.5128G>A p.E1710K (on ENST00000376460 / NM_001366676.2; = p.E1711K on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EPHA10 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 90/157 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM187A | c.1096C>G p.P366A | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM193A | c.3266del p.L1089Pfs*24 | Frame Shift Del (DEL) | VAF 112/120 reads (93%) | called by mutect2, pindel*, varscan2
- FANK1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 204/227 reads (90%) | called by muse, mutect2, varscan2
- FIBIN | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- FOLH1 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 64/85 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FRMD8 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 369/396 reads (93%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNA15 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- GNB3 | c.518C>G p.T173S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT tolerated (0.93); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GTF2A1 | c.402+1G>C p.X134_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- HEATR6 | c.2533C>T p.P845S | Missense Mutation (SNP) | VAF 148/219 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IGFBP1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- IL23R | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 77/130 reads (59%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCNE2 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNG1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 251/726 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH8 | c.3256G>A p.E1086K | Missense Mutation (SNP) | VAF 94/104 reads (90%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- KIF19 | c.2437C>G p.H813D | Missense Mutation (SNP) | VAF 9/271 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- KRT18 | c.501-7C>A | Splice Region (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- LAMC3 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 189/206 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LINC00574 | n.360+7C>G | Splice Region (SNP) | VAF 138/146 reads (95%) | called by muse, mutect2, varscan2
- LRRC7 | c.3890G>A p.G1297E (on ENST00000651989 / NM_001370785.2; = p.G1264E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- MAGEL2 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAGI3 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- MARCHF6 | c.1466C>T p.S489F | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MCM5 | c.-8-1G>A | Splice Site (SNP) | VAF 91/589 reads (15%) | called by muse, mutect2, varscan2
- MINDY2 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 168/351 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.3067T>C p.C1023R | Missense Mutation (SNP) | VAF 101/160 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MRPL44 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MS4A15 | c.347G>A p.C116Y (on ENST00000405633 / NM_001098835.2; = p.C23Y on NM_152717.3) | Missense Mutation (SNP) | VAF 52/54 reads (96%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- MSL3 | c.1435G>T p.A479S (on ENST00000312196 / NM_078629.4; = p.A313S on NM_006800.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUCL3 | c.14T>A p.V5D | Missense Mutation (SNP) | VAF 132/314 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- MYCBP2 | c.2003G>A p.G668D (on ENST00000357337; = p.G706D on NM_015057.5) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO5A | c.2844G>C p.E948D | Missense Mutation (SNP) | VAF 104/214 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- NAALADL2 | c.469T>G p.S157A | Missense Mutation (SNP) | VAF 90/166 reads (54%) | SIFT tolerated (0.11); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- NID2 | c.3344G>A p.G1115D | Missense Mutation (SNP) | VAF 123/236 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- NR1I2 | c.321G>A p.M107I | Missense Mutation (SNP) | VAF 145/283 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NT5C1B | c.1169G>A p.G390E (on ENST00000359846 / NM_001199086.2; = p.G330E on NM_033253.4) | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OBSCN | c.15134C>T p.P5045L | Missense Mutation (SNP) | VAF 211/440 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- OR2AP1 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 105/164 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PCDHB11 | c.1438T>G p.S480A | Missense Mutation (SNP) | VAF 140/576 reads (24%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- PCDHB16 | c.2183C>T p.P728L | Missense Mutation (SNP) | VAF 147/436 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- PHF20L1 | c.2821C>T p.L941F | Missense Mutation (SNP) | VAF 70/194 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PPRC1 | c.3623C>T p.P1208L | Missense Mutation (SNP) | VAF 73/74 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- PRLR | c.443G>A p.W148* | Nonsense Mutation (SNP) | VAF 108/192 reads (56%) | called by muse, mutect2, varscan2
- PRR14L | c.3497_3504del p.K1166Ifs*10 | Frame Shift Del (DEL) | VAF 52/173 reads (30%) | called by mutect2, pindel, varscan2
- PWWP2B | c.1543_1570del p.Q515Efs*30 | Frame Shift Del (DEL) | VAF 93/114 reads (82%) | called by mutect2, pindel, varscan2
- QSER1 | c.3569C>T p.P1190L (on ENST00000399302; = p.P1319L on NM_001076786.3) | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.15); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RASAL3 | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- RECQL4 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 275/639 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- RPL7L1 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- RPS4Y1 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 184/199 reads (92%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SACS | c.6771G>T p.L2257F | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SERPINF2 | c.136C>G p.P46A | Missense Mutation (SNP) | VAF 54/349 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SETD1B | c.4054C>T p.P1352S | Missense Mutation (SNP) | VAF 102/165 reads (62%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- SIK2 | c.424_425insT p.D142Vfs*5 | Frame Shift Ins (INS) | VAF 112/174 reads (64%) | called by mutect2, pindel, varscan2
- SIM1 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- SKA3 | c.345A>C p.E115D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- SKIDA1 | c.1929A>T p.E643D | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT tolerated (0.11); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SLC25A48 | c.615G>A p.W205* (on ENST00000650267; = p.W151* on NM_001349335.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 166/281 reads (59%) | called by muse, mutect2, varscan2
- SLC30A10 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 199/403 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC37A1 | c.1500del p.F500Lfs*10 | Frame Shift Del (DEL) | VAF 87/233 reads (37%) | called by mutect2, pindel, varscan2
- SLC4A8 | c.103A>C p.I35L | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SLCO6A1 | c.698T>A p.I233N | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SLFN11 | c.114G>T p.Q38H | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- SORBS2 | c.3085-8C>T | Splice Region (SNP) | VAF 47/49 reads (96%) | called by muse, mutect2, varscan2
- SPTA1 | c.5279G>A p.G1760E | Missense Mutation (SNP) | VAF 205/451 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SSTR1 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- STARD13 | c.1771C>T p.Q591* (on ENST00000336934 / NM_001243476.3; = p.Q473* on NM_052851.3) | Nonsense Mutation (SNP) | VAF 48/133 reads (36%) | called by muse, mutect2, varscan2
- STUB1 | c.337G>C p.A113P | Missense Mutation (SNP) | VAF 31/334 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SULT1C4 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM184A | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- TRPC4 | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- TRPC6 | c.2530C>G p.H844D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRPM1 | c.3109G>A p.E1037K | Missense Mutation (SNP) | VAF 193/398 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TSGA10 | c.1738C>G p.Q580E | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- TSPOAP1 | c.4046G>A p.G1349E | Missense Mutation (SNP) | VAF 232/352 reads (66%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TXNRD3 | c.774G>A p.W258* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- TXNRD3 | c.773G>A p.W258* | Nonsense Mutation (SNP) | VAF 25/75 reads (33%) | called by muse, mutect2, varscan2
- UNC13B | c.4713C>G p.D1571E | Missense Mutation (SNP) | VAF 172/187 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDFY4 | c.8363G>A p.S2788N | Missense Mutation (SNP) | VAF 153/171 reads (89%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB9 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF512B | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 252/422 reads (60%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ZNF726 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZNF777 | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 65/175 reads (37%) | called by muse, mutect2, varscan2
- ZNF841 | c.2018G>A p.G673E (on ENST00000426391 / NM_001369830.1; = p.G789E on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM5 | c.2633C>T p.S878L | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCC1 | c.3210G>A p.G1070= | Silent (SNP) | VAF 177/339 reads (52%) | catalogued as rs761447728; called by muse, mutect2, varscan2
- ACACA | c.3687G>A p.G1229= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- ACTL6B | c.156G>A p.L52= | Silent (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.2937G>A p.E979= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs768200315; called by muse, mutect2, varscan2
- ANO1 | c.2505C>T p.L835= | Silent (SNP) | VAF 68/78 reads (87%) | catalogued as COSV62448947; called by muse, mutect2, varscan2
- APOBEC3F | c.855G>A p.G285= | Silent (SNP) | VAF 112/669 reads (17%) | called by muse, mutect2, varscan2
- ATP6V0D2 | c.465G>A p.L155= | Silent (SNP) | VAF 90/95 reads (95%) | called by muse, mutect2, varscan2
- ATRN | c.2574C>T p.G858= | Silent (SNP) | VAF 260/395 reads (66%) | called by muse, mutect2, varscan2
- BARD1 | c.828T>C p.T276= | Silent (SNP) | VAF 16/22 reads (73%) | called by muse, mutect2, varscan2
- BSN | c.8370C>A p.S2790= | Silent (SNP) | VAF 56/125 reads (45%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.81C>T p.F27= | Silent (SNP) | VAF 49/228 reads (21%) | catalogued as rs749582451; called by muse, mutect2, varscan2
- CD207 | c.786G>A p.G262= | Silent (SNP) | VAF 112/277 reads (40%) | catalogued as COSV69652562; called by muse, mutect2, varscan2
- CDC42BPB | c.2652G>A p.E884= | Silent (SNP) | VAF 74/202 reads (37%) | catalogued as rs766149282; called by muse, mutect2, varscan2
- CDH5 | c.279C>T p.F93= | Silent (SNP) | VAF 116/132 reads (88%) | called by muse, mutect2, varscan2
- CHGB | c.76A>C p.R26= | Silent (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- COX4I2 | c.190C>T p.L64= | Silent (SNP) | VAF 191/650 reads (29%) | called by muse, mutect2, varscan2
- CR2 | c.621C>T p.P207= | Silent (SNP) | VAF 239/541 reads (44%) | catalogued as rs573346582, COSV100889572, COSV100889648; called by muse, mutect2, varscan2
- CYP19A1 | c.48C>T p.I16= | Silent (SNP) | VAF 240/574 reads (42%) | catalogued as rs375851874; called by muse, mutect2, varscan2
- DCAF4L2 | c.651C>T p.H217= | Silent (SNP) | VAF 403/418 reads (96%) | called by muse, mutect2, varscan2
- DDX56 | c.642C>T p.N214= | Silent (SNP) | VAF 101/213 reads (47%) | catalogued as rs1298596383; called by muse, mutect2, varscan2
- DPYS | c.1500G>A p.L500= | Silent (SNP) | VAF 198/436 reads (45%) | catalogued as rs1471893144, COSV60913636; called by muse, mutect2, varscan2
- EPHA4 | c.1209C>T p.L403= | Silent (SNP) | VAF 96/175 reads (55%) | catalogued as COSV56026807; called by muse, mutect2, varscan2
- EPX | c.816C>T p.D272= | Silent (SNP) | VAF 158/251 reads (63%) | catalogued as rs1194693242; called by muse, mutect2, varscan2
- ERBB2 | c.1602C>T p.F534= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as rs1299820476; called by muse, mutect2, varscan2
- FASTKD1 | c.2421T>C p.I807= | Silent (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- FLVCR1 | c.1323T>C p.G441= | Silent (SNP) | VAF 131/274 reads (48%) | called by muse, mutect2, varscan2
- FOXQ1 | c.819C>T p.I273= | Silent (SNP) | VAF 11/273 reads (4%) | called by muse, mutect2
- FZD8 | c.1327C>T p.L443= | Silent (SNP) | VAF 214/235 reads (91%) | called by muse, mutect2, varscan2
- GALNT14 | c.336C>T p.P112= | Silent (SNP) | VAF 131/310 reads (42%) | called by muse, mutect2, varscan2
- GNAT2 | c.780G>A p.A260= | Silent (SNP) | VAF 97/179 reads (54%) | catalogued as rs776207301; called by muse, mutect2, varscan2
- GPX6 | c.45G>A p.L15= | Silent (SNP) | VAF 16/309 reads (5%) | catalogued as COSV100724767; called by muse, mutect2
- GRM3 | c.888C>T p.T296= | Silent (SNP) | VAF 122/273 reads (45%) | catalogued as COSV100862964; called by muse, varscan2
- HDLBP | c.1059G>A p.A353= | Silent (SNP) | VAF 61/248 reads (25%) | catalogued as COSV100190567, COSV60494654; called by muse, mutect2, varscan2
- HMCN1 | c.11997C>T p.V3999= | Silent (SNP) | VAF 64/146 reads (44%) | catalogued as rs1558237766; called by muse, mutect2, varscan2
- JAKMIP1 | c.18G>A p.R6= | Silent (SNP) | VAF 108/121 reads (89%) | catalogued as COSV99290537; called by muse, mutect2, varscan2
- KDM7A | c.474C>T p.V158= | Silent (SNP) | VAF 79/201 reads (39%) | catalogued as rs1345145985; called by muse, mutect2, varscan2
- KIF19 | c.1380C>T p.T460= | Silent (SNP) | VAF 115/179 reads (64%) | called by muse, mutect2, varscan2
- KPNA2 | c.778C>T p.L260= | Silent (SNP) | VAF 93/313 reads (30%) | called by muse, mutect2, varscan2
- LRP1 | c.5967C>T p.I1989= | Silent (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- MAP3K21 | c.1557C>T p.F519= | Silent (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2
- MUCL3 | c.12G>A p.P4= | Silent (SNP) | VAF 129/306 reads (42%) | catalogued as rs747381496; called by muse, mutect2
- MYO18B | c.3345C>T p.P1115= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2
- MZF1 | c.1836C>T p.L612= | Silent (SNP) | VAF 134/414 reads (32%) | called by muse, mutect2, varscan2
- NCKAP5 | c.1374G>A p.G458= | Silent (SNP) | VAF 86/161 reads (53%) | catalogued as rs1251295796, COSV100492048, COSV100494722; called by muse, mutect2, varscan2
- OR10X1 | c.120G>A p.Q40= | Silent (SNP) | VAF 51/173 reads (29%) | catalogued as COSV100936588; called by muse, mutect2, varscan2
- OR2L2 | c.876A>G p.R292= | Silent (SNP) | VAF 70/135 reads (52%) | called by muse, mutect2, varscan2
- OR2M3 | c.558C>A p.I186= | Silent (SNP) | VAF 99/213 reads (46%) | called by muse, mutect2, varscan2
- OR2T29 | c.150C>T p.I50= | Silent (SNP) | VAF 112/475 reads (24%) | catalogued as COSV100148237; called by muse, mutect2
- OR51D1 | c.72C>T p.F24= | Silent (SNP) | VAF 131/139 reads (94%) | catalogued as COSV62913866; called by muse, mutect2, varscan2
- PCGF2 | c.129C>T p.I43= | Silent (SNP) | VAF 98/271 reads (36%) | catalogued as rs773058117; called by muse, mutect2, varscan2
- PCIF1 | c.897C>T p.I299= | Silent (SNP) | VAF 80/252 reads (32%) | called by muse, mutect2, varscan2
- PLOD3 | c.1912C>T p.L638= | Silent (SNP) | VAF 109/234 reads (47%) | catalogued as rs137991909; called by muse, mutect2, varscan2
- POLR2A | c.2010C>T p.S670= | Silent (SNP) | VAF 59/186 reads (32%) | called by muse, mutect2, varscan2
- PRRC2B | c.3846C>T p.F1282= | Silent (SNP) | VAF 51/52 reads (98%) | catalogued as rs766732139; called by muse, mutect2, varscan2
- PSMG1 | c.384C>T p.S128= | Silent (SNP) | VAF 16/16 reads (100%) | catalogued as COSV100312975; called by muse, mutect2, varscan2
- RASAL3 | c.1572C>T p.T524= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as COSV100640335; called by muse, mutect2, varscan2
- SCN2A | c.4005A>T p.P1335= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- SEMA5A | c.2094C>T p.T698= | Silent (SNP) | VAF 66/227 reads (29%) | catalogued as COSV66808188; called by muse, mutect2, varscan2
- SIGLEC12 | c.963C>T p.I321= (on ENST00000291707 / NM_053003.4; = p.I203= on NM_033329.2) | Silent (SNP) | VAF 110/172 reads (64%) | catalogued as COSV52463112, COSV99389619; called by muse, mutect2, varscan2
- SIM1 | c.1194G>A p.S398= | Silent (SNP) | VAF 26/27 reads (96%) | catalogued as rs200807053; called by muse, varscan2
- SLAMF8 | c.471C>T p.I157= | Silent (SNP) | VAF 129/338 reads (38%) | catalogued as COSV56987351; called by muse, mutect2, varscan2
- SLCO6A1 | c.699C>A p.I233= | Silent (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- SPHKAP | c.1593G>A p.G531= | Silent (SNP) | VAF 108/175 reads (62%) | catalogued as COSV60896080; called by muse, mutect2, varscan2
- STARD13 | c.1770C>T p.F590= (on ENST00000336934 / NM_001243476.3; = p.F472= on NM_052851.3) | Silent (SNP) | VAF 47/131 reads (36%) | catalogued as rs1044083856; called by muse, mutect2, varscan2
- STK32C | c.444C>T p.I148= | Silent (SNP) | VAF 208/227 reads (92%) | catalogued as rs751343663, COSV100062188; called by muse, mutect2, varscan2
- TFRC | c.498G>A p.A166= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs372473096; called by muse, mutect2, varscan2
- TLN2 | c.5985C>T p.T1995= | Silent (SNP) | VAF 77/360 reads (21%) | catalogued as rs780484556; called by muse, mutect2, varscan2
- TMEM184A | c.600C>T p.T200= | Silent (SNP) | VAF 104/229 reads (45%) | catalogued as rs745933432; called by muse, mutect2, varscan2
- TNR | c.4050G>A p.G1350= | Silent (SNP) | VAF 86/191 reads (45%) | catalogued as rs758911710; called by muse, mutect2, varscan2
- TRAV38-1 | c.165C>T p.F55= | Silent (SNP) | VAF 58/147 reads (39%) | catalogued as rs1232134210; called by muse, mutect2, varscan2
- TRBJ2-1 | c.24C>T p.F8= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs782655105; called by muse, mutect2, varscan2
- TRPV4 | c.1779C>T p.T593= | Silent (SNP) | VAF 334/585 reads (57%) | catalogued as COSV99924753; called by muse, mutect2, varscan2
- TRRAP | c.5286C>T p.P1762= (on ENST00000359863 / NM_001244580.1; = p.P1744= on NM_003496.3) | Silent (SNP) | VAF 93/221 reads (42%) | catalogued as rs782670281; called by muse, mutect2, varscan2
- TTK | c.579G>A p.Q193= | Silent (SNP) | VAF 66/72 reads (92%) | called by muse, mutect2, varscan2
- U2SURP | c.2598A>G p.K866= | Silent (SNP) | VAF 41/90 reads (46%) | catalogued as COSV67530277; called by muse, mutect2, varscan2
- UGT1A10 | c.147C>A p.I49= | Silent (SNP) | VAF 76/285 reads (27%) | called by muse, mutect2, varscan2
- URB1 | c.4077C>T p.I1359= | Silent (SNP) | VAF 60/70 reads (86%) | catalogued as rs747425388, COSV66958244; called by muse, mutect2, varscan2
- WARS2 | c.336C>T p.F112= | Silent (SNP) | VAF 55/99 reads (56%) | called by muse, mutect2, varscan2
- WRAP53 | c.969C>T p.G323= | Silent (SNP) | VAF 221/355 reads (62%) | catalogued as COSV99872898; called by muse, mutect2, varscan2
- ZNF208 | c.1377C>T p.G459= | Silent (SNP) | VAF 70/222 reads (32%) | catalogued as rs543555168; called by muse, mutect2
- AACS | c.358+1631A>G | Intron (SNP) | VAF 165/546 reads (30%) | called by muse, mutect2, varscan2
- AC093642.3 | n.2990G>A | RNA (SNP) | VAF 312/816 reads (38%) | called by muse, varscan2
- ASL | c.348+27C>T | Intron (SNP) | VAF 300/672 reads (45%) | called by muse, mutect2, varscan2
- C9orf62 | n.421G>T | RNA (SNP) | VAF 72/165 reads (44%) | called by muse, mutect2, varscan2
- CCK | c.214+78A>C | Intron (SNP) | VAF 93/237 reads (39%) | called by muse, mutect2, varscan2
- CELA3A | c.795+295C>A | Intron (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- CHTF18 | chr16:788304 del GGCTCCAGCCGCGCGCCCGCGCGCT | 5'Flank (DEL) | VAF 30/109 reads (28%) | catalogued as rs1404179234; called by mutect2, pindel, varscan2
- CLIP2 | c.*2C>T | 3'UTR (SNP) | VAF 192/481 reads (40%) | catalogued as rs782001194; called by muse, mutect2, varscan2
- CSNK1A1 | c.456+2451G>A | Intron (SNP) | VAF 54/95 reads (57%) | catalogued as COSV55796018; called by muse, mutect2, varscan2
- CTCFL | c.1674+791C>T | Intron (SNP) | VAF 80/517 reads (15%) | called by muse, mutect2, varscan2
- CYP19A1 | c.*403A>C | 3'UTR (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- ECM1 | c.304+45C>T | Intron (SNP) | VAF 113/254 reads (44%) | called by muse, mutect2, varscan2
- FAAP20 | c.-19C>T | 5'UTR (SNP) | VAF 9/15 reads (60%) | catalogued as rs1208044567; called by muse, mutect2, varscan2
- FRA10AC1 | c.*59T>G | 3'UTR (SNP) | VAF 25/30 reads (83%) | called by muse, varscan2
- GCNT2 | c.926-35106A>C | Intron (SNP) | VAF 224/508 reads (44%) | called by muse, mutect2, varscan2
- GUCY2D | c.2576+14G>A | Intron (SNP) | VAF 233/394 reads (59%) | called by muse, mutect2, varscan2
- HSD17B4 | c.-105T>C | 5'UTR (SNP) | VAF 158/244 reads (65%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-3264G>A | Intron (SNP) | VAF 72/194 reads (37%) | called by muse, mutect2
- IGFN1 | c.1242-2940G>A | Intron (SNP) | VAF 138/304 reads (45%) | called by muse, varscan2
- IGFN1 | c.1242-753G>A | Intron (SNP) | VAF 42/138 reads (30%) | called by muse, mutect2, varscan2
- KCND2 | c.1375-12C>T | Intron (SNP) | VAF 203/409 reads (50%) | called by muse, mutect2, varscan2
- LINC00174 | n.3212C>T | RNA (SNP) | VAF 64/282 reads (23%) | called by muse, mutect2, varscan2
- NANOGP1 | n.713C>T | RNA (SNP) | VAF 155/388 reads (40%) | called by muse, mutect2, varscan2
- NARF | c.521-220C>T | Intron (SNP) | VAF 67/189 reads (35%) | called by muse, mutect2, varscan2
- NDUFAF1 | c.-318G>A | 5'UTR (SNP) | VAF 54/102 reads (53%) | called by muse, mutect2, varscan2
- NEIL1 | c.*1235G>A | 3'UTR (SNP) | VAF 149/310 reads (48%) | catalogued as rs772044607; called by muse, mutect2, varscan2
- NEXN | c.*115_*116del | 3'UTR (DEL) | VAF 12/111 reads (11%) | called by mutect2, varscan2
- OR4N3P | n.342C>T | RNA (SNP) | VAF 162/472 reads (34%) | catalogued as rs1163508892; called by muse, mutect2, varscan2
- OSTCP1 | n.281G>A | RNA (SNP) | VAF 107/113 reads (95%) | called by muse, mutect2, varscan2
- PHLDB2 | c.2873-76G>A | Intron (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.424-65777G>A | Intron (SNP) | VAF 89/320 reads (28%) | catalogued as rs1466275865; called by muse, mutect2, varscan2
- PLEKHG7 | c.530+23C>T | Intron (SNP) | VAF 64/121 reads (53%) | catalogued as rs772869067, COSV67338047; called by muse, mutect2, varscan2
- POLD1 | c.1776-9C>T | Intron (SNP) | VAF 82/218 reads (38%) | catalogued as rs1555791748; ClinVar: likely benign; called by muse, varscan2
- POLR3B | c.2985-1189C>T | Intron (SNP) | VAF 80/144 reads (56%) | catalogued as rs766848688; called by muse, mutect2
- SATL1 | c.-368A>G | 5'UTR (SNP) | VAF 220/230 reads (96%) | catalogued as COSV100261071; called by muse, mutect2, varscan2
- SCN1B | c.448+176_448+177del | Intron (DEL) | VAF 62/194 reads (32%) | called by mutect2, pindel, varscan2
- SORBS1 | c.2129-999A>G | Intron (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3454G>A | Intron (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3453T>C | Intron (SNP) | VAF 48/83 reads (58%) | called by muse, mutect2, varscan2
- ST13 | c.681+410C>T | Intron (SNP) | VAF 56/69 reads (81%) | called by muse, mutect2, varscan2
- TMEM184B | c.359-60C>T | Intron (SNP) | VAF 124/658 reads (19%) | catalogued as rs749649941; called by muse, mutect2, varscan2
- UBE2F | c.*23C>T | 3'UTR (SNP) | VAF 41/108 reads (38%) | catalogued as rs1417295696; called by muse, mutect2, varscan2
- UBR7 | c.*1787C>T | 3'UTR (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- WASHC5 | c.2505-33C>T | Intron (SNP) | VAF 112/238 reads (47%) | called by muse, mutect2, varscan2
- YJU2 | chr19:4247063 G>A | 5'Flank (SNP) | VAF 89/269 reads (33%) | called by muse, mutect2, varscan2
- ZNF165 | chr6:28091373 C>T | 3'Flank (SNP) | VAF 235/416 reads (56%) | called by muse, mutect2, varscan2
- ZSWIM4 | c.1180+1517G>A | Intron (SNP) | VAF 35/52 reads (67%) | catalogued as rs770212002, COSV99585647; called by muse, mutect2, varscan2
